Somatic mutation profile of tumor specimen TCGA-E5-A4U1-01A (aliquot TCGA-E5-A4U1-01A-11D-A31L-08) from TCGA case TCGA-E5-A4U1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 72.0 years (26,305 days).
Specimen TCGA-E5-A4U1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 295b5569-1ef4-4d76-93f2-135f9fd3815f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E5-A4U1-10B (Blood Derived Normal), aliquot TCGA-E5-A4U1-10B-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f7147cf-68f1-4fdd-b5eb-f04a0eab6684

The open-access MAF lists 625 somatic variants for this specimen: 464 protein-altering or splice-affecting, 150 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 398, Silent 150, Nonsense Mutation 51, Splice Site 5, Splice Region 4, Frame Shift Del 4, Intron 3, RNA 3, 3'UTR 3, 3'Flank 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 74/131 reads (56%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 16/20 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 3/43 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV52919029, COSV53016463, COSV53587568; called by muse, mutect2
- ABCA12 | c.1662G>T p.Q554H (on ENST00000272895 / NM_173076.3; = p.Q236H on NM_015657.3) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as COSV55970862; called by muse, mutect2, varscan2
- ABCA3 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100068361; called by muse, mutect2
- ABHD10 | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.338); catalogued as COSV56325962; called by muse, mutect2, varscan2
- ABLIM1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.014); catalogued as COSV53301835, COSV53317271; called by muse, mutect2, varscan2
- AC131160.1 | c.718C>G p.L240V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57701784; called by muse, mutect2
- ACACB | c.2163G>C p.L721F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58142801; called by muse, mutect2
- ACAD9 | c.293T>C p.L98S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1012004126, CM153910, COSV58309413; called by muse, mutect2, varscan2
- ACOX1 | c.153G>C p.L51F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV53133830, COSV53135592; called by muse, mutect2, varscan2
- ACSL1 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV99860568; called by muse, mutect2, varscan2
- ACSS3 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54098635; called by muse, mutect2, varscan2
- ACTR8 | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51638056; called by muse, mutect2, varscan2
- ADAM29 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.245); catalogued as COSV63664622; called by muse, mutect2, varscan2
- ADAM29 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV63664471; called by muse, mutect2, varscan2
- ADCK5 | c.1470C>G p.I490M | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV58235087; called by muse, mutect2, varscan2
- ADCY7 | c.2916G>C p.M972I | Missense Mutation (SNP) | VAF 117/170 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as COSV54269719; called by muse, mutect2, varscan2
- ADGRD1 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV55453615; called by muse, mutect2
- ADRB1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.541); catalogued as COSV65168241; called by muse, mutect2
- ADSS1 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV58273434, COSV58275495; called by muse, mutect2, varscan2
- AFF3 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs1434062146, COSV57867285, COSV57868032; called by muse, mutect2, varscan2
- AGGF1 | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 101/163 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as COSV57230380, COSV57230748; called by muse, mutect2, varscan2
- AKAP13 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV63466099; called by muse, mutect2
- ANK1 | c.3157C>T p.R1053* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as CM032179, COSV99224902; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5768C>G p.S1923* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99782966; called by muse, mutect2, varscan2
- ANKS1A | c.1314G>C p.M438I | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV64463364; called by muse, varscan2
- ANKS1A | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64463371; called by muse, varscan2
- APLP2 | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV53843389; called by muse, mutect2, varscan2
- ARHGAP17 | c.1128-1G>C p.X376_splice | Splice Site (SNP) | VAF 5/83 reads (6%) | catalogued as COSV51504787; called by muse, mutect2
- ARHGAP31 | c.3404C>G p.S1135C | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51797326; called by muse, mutect2, varscan2
- ARHGEF10 | c.3889C>G p.L1297V (on ENST00000398564; = p.L1272V on NM_014629.4) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as rs1563343055, COSV50668150; called by muse, mutect2
- ARHGEF19 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV54616219, COSV54618071; called by muse, mutect2, varscan2
- ASCC3 | c.1020T>G p.Y340* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100225604; called by muse, mutect2, varscan2
- ASIC4 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV61732946; called by muse, mutect2, varscan2
- ASXL1 | c.1331C>G p.S444* | Nonsense Mutation (SNP) | VAF 83/276 reads (30%) | catalogued as rs373126831, COSV60118145; called by muse, mutect2, varscan2
- ATF4 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV100307643; called by muse, mutect2, varscan2
- ATMIN | c.866G>C p.R289T | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV55147164; called by muse, mutect2, varscan2
- ATN1 | c.1967G>C p.G656A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.003); catalogued as COSV100755935, COSV63112582; called by muse, mutect2, varscan2
- ATP1A3 | c.2508G>C p.K836N (on ENST00000545399 / NM_001256214.2; = p.K823N on NM_152296.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.468); catalogued as COSV57490300; called by muse, mutect2, varscan2
- ATP2A2 | c.2575G>A p.D859N | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV57876074; called by muse, mutect2, varscan2
- ATP8A1 | c.2594A>G p.K865R | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100047293, COSV52544786; called by muse, mutect2, varscan2
- AZGP1 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV52798962; called by muse, mutect2, varscan2
- B3GNT8 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV54199127; called by muse, mutect2, varscan2
- B3GNTL1 | c.330C>G p.C110W | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57952529; called by muse, mutect2, varscan2
- BAG4 | c.455C>G p.S152* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99781800; called by muse, mutect2, varscan2
- BARHL2 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 44/79 reads (56%) | catalogued as COSV100966048; called by muse, mutect2, varscan2
- BAZ1A | c.4217G>C p.R1406T | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.212); catalogued as COSV62411754; called by muse, mutect2, varscan2
- BCL2L13 | c.1366G>T p.E456* | Nonsense Mutation (SNP) | VAF 50/158 reads (32%) | catalogued as COSV100456244; called by muse, mutect2, varscan2
- BDP1 | c.4120G>A p.E1374K | Missense Mutation (SNP) | VAF 59/96 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV62430746, COSV62433493; called by muse, mutect2, varscan2
- BICC1 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV54065822; called by muse, mutect2, varscan2
- BICRA | c.4583C>T p.S1528L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs1342212329, COSV67605964; called by muse, mutect2
- BIRC6 | c.1319C>T p.S440L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV70204005; called by muse, mutect2
- BIRC6 | c.14138G>T p.R4713L | Missense Mutation (SNP) | VAF 83/144 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70195568, COSV70198344; called by muse, mutect2, varscan2
- BLNK | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV56414019; called by muse, mutect2, varscan2
- BPIFB6 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV62756282; called by muse, mutect2
- BSN | c.8896G>C p.D2966H | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56525040; called by muse, mutect2, varscan2
- BTNL2 | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100896047; called by muse, mutect2
- BTNL8 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV51460766, COSV51461851; called by muse, mutect2
- BUD31 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV52866609; called by muse, mutect2, varscan2
- C1orf35 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV55255678; called by muse, mutect2, varscan2
- C1orf43 | c.128G>C p.R43P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV55178857; called by muse, mutect2, varscan2
- C21orf58 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV99388011; called by muse, mutect2, varscan2
- C3AR1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.067); catalogued as COSV50822200; called by muse, mutect2, varscan2
- C7orf50 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs766500876, COSV62477515; called by muse, mutect2, varscan2
- C8orf37 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54413455; called by muse, mutect2
- CAMTA1 | c.3709C>T p.H1237Y | Missense Mutation (SNP) | VAF 89/146 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV57920198; called by muse, mutect2, varscan2
- CARD11 | c.660G>A p.M220I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62719107, COSV62720212; called by muse, mutect2, varscan2
- CBY2 | c.617C>G p.S206W | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV60117923, COSV60119400; called by muse, mutect2, varscan2
- CCDC146 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as COSV99592440, COSV99592502; called by muse, mutect2, varscan2
- CCDC39 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 82/248 reads (33%) | catalogued as COSV56487428; called by muse, mutect2, varscan2
- CCDC62 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV53436313; called by muse, mutect2
- CCNJL | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV57446149, COSV99979429; called by muse, mutect2, varscan2
- CCP110 | c.2516C>G p.S839* | Nonsense Mutation (SNP) | VAF 29/179 reads (16%) | catalogued as COSV101195260; called by muse, mutect2, varscan2
- CD163L1 | c.2687-1G>A p.X896_splice | Splice Site (SNP) | VAF 31/48 reads (65%) | catalogued as rs138525217; called by muse, mutect2, varscan2
- CDCA5 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV51870876; called by muse, mutect2, varscan2
- CDH12 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 59/79 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200251715, COSV66426603, COSV66435681; called by muse, mutect2, varscan2
- CDH13 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51855887; called by muse, mutect2, varscan2
- CDH17 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | catalogued as COSV99217326; called by muse, mutect2, varscan2
- CDH7 | c.1333A>G p.N445D | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.366); catalogued as COSV59891983; called by muse, mutect2, varscan2
- CDK16 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV99331644; called by muse, mutect2
- CEP76 | c.1019C>G p.A340G | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50868933; called by muse, mutect2, varscan2
- CERS6 | c.165C>G p.F55L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV59834059; called by muse, mutect2, varscan2
- CES1 | c.579C>G p.D193E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62089393; called by muse, mutect2, varscan2
- CFAP43 | c.3408G>C p.L1136F | Missense Mutation (SNP) | VAF 20/708 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63854575; called by muse, mutect2
- CFAP46 | c.6964G>C p.E2322Q | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as COSV54157120; called by muse, mutect2
- CFAP70 | c.1450G>C p.E484Q | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60285792; called by muse, mutect2
- CHD5 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 176/319 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV52422331; called by muse, mutect2, varscan2
- CHSY3 | c.1123C>T p.R375W | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1033562678, COSV59275201; called by muse, mutect2, varscan2
- CLCN2 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55603468; called by muse, mutect2, varscan2
- CLEC7A | c.202G>C p.A68P (on ENST00000304084 / NM_197947.3; = p.G68R on NM_022570.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.832); catalogued as COSV100021121; called by muse, mutect2
- CLSPN | c.2799G>C p.K933N | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); catalogued as COSV52055707; called by muse, mutect2, varscan2
- CLVS2 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.718); catalogued as COSV51565746, COSV51567685; called by muse, mutect2, varscan2
- CNNM2 | c.525C>G p.I175M | Missense Mutation (SNP) | VAF 15/376 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.268); catalogued as COSV100881625, COSV63996334; called by muse, mutect2
- CNTNAP4 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56695033; called by muse, mutect2, varscan2
- COL10A1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.875); catalogued as COSV54574207; called by muse, mutect2, varscan2
- COL4A3 | c.3805G>C p.D1269H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV59259146; called by muse, mutect2, varscan2
- COL4A4 | c.2759G>C p.R920T | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); catalogued as COSV100306689, COSV61636250; called by muse, mutect2
- COQ8A | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.007); catalogued as COSV64658836; called by muse, mutect2, varscan2
- CPD | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56715312; called by muse, mutect2, varscan2
- CREBRF | c.1795G>C p.D599H | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV51635455; called by muse, mutect2
- CRYM | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 64/84 reads (76%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV54832635; called by muse, mutect2, varscan2
- CSRNP1 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56189500; called by muse, mutect2
- CTCF | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 152/409 reads (37%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.982); catalogued as COSV50499955; called by muse, mutect2, varscan2
- CTNND1 | c.2830C>G p.L944V (on ENST00000399050 / NM_001085458.2; = p.L917V on NM_001331.3) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.099); catalogued as COSV62383167, COSV62385348; called by muse, mutect2, varscan2
- CXCR5 | c.1103C>G p.S368C | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV52688051, COSV99420437; called by muse, mutect2, varscan2
- CXorf66 | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV65169647; called by muse, mutect2, varscan2
- CYRIA | c.567C>A p.F189L | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62866556; called by muse, mutect2, varscan2
- DAB2 | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV57917792; called by muse, mutect2, varscan2
- DAZAP1 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 50/86 reads (58%) | catalogued as COSV51831873, COSV51833701, COSV99245075; called by muse, varscan2
- DCAF8L1 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.037); catalogued as COSV71595465; called by muse, mutect2, varscan2
- DCT | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.07); catalogued as COSV65470385; called by muse, mutect2, varscan2
- DDX20 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774790226, COSV63780831; called by muse, mutect2, varscan2
- DDX43 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as rs1366952611, COSV100943953; called by muse, mutect2
- DENND2A | c.1931G>A p.R644K | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1433774431, COSV52056758; called by muse, mutect2, varscan2
- DENND4A | c.686C>A p.S229Y | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71266781; called by muse, mutect2, varscan2
- DESI1 | c.291-1G>C p.X97_splice | Splice Site (SNP) | VAF 51/135 reads (38%) | catalogued as COSV54355102; called by muse, mutect2, varscan2
- DGKB | c.1597C>A p.L533M | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51809382; called by muse, mutect2, varscan2
- DGLUCY | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV56369270; called by muse, mutect2
- DIP2C | c.3027G>C p.K1009N | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV55173524; called by muse, mutect2, varscan2
- DLGAP2 | c.2402C>A p.S801* | Nonsense Mutation (SNP) | VAF 34/43 reads (79%) | catalogued as COSV101421712; called by muse, mutect2, varscan2
- DMBT1 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 124/254 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57555316; called by muse, mutect2, varscan2
- DMD | c.5949G>T p.M1983I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63780492; called by muse, mutect2, varscan2
- DMXL1 | c.5411C>G p.S1804* | Nonsense Mutation (SNP) | VAF 28/44 reads (64%) | catalogued as COSV100223808; called by muse, mutect2, varscan2
- DMXL2 | c.8152C>T p.R2718C | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as rs758537533, COSV51853206; called by muse, mutect2, varscan2
- DNAAF1 | c.945G>T p.K315N | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57578465; called by muse, mutect2
- DNAH8 | c.12643G>A p.E4215K | Missense Mutation (SNP) | VAF 7/162 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV59471309; called by muse, mutect2
- DNMT1 | c.2445C>G p.F815L | Missense Mutation (SNP) | VAF 48/880 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV61582394; called by muse, mutect2
- DOCK2 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as COSV56979415; called by muse, mutect2, varscan2
- DOCK2 | c.3625-1G>C p.X1209_splice | Splice Site (SNP) | VAF 41/71 reads (58%) | catalogued as COSV56979423; called by muse, mutect2, varscan2
- DOCK9 | c.787G>A p.D263N (on ENST00000376460 / NM_001366676.2; = p.D264N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV59631528; called by muse, mutect2, varscan2
- DPH1 | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 61/72 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV53986024; called by muse, mutect2, varscan2
- DSC3 | c.2209A>T p.T737S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64574690; called by muse, mutect2, varscan2
- DSCAML1 | c.3254G>A p.G1085D (on ENST00000321322; = p.G1025D on NM_020693.4) | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1490985807, COSV58399555; called by muse, mutect2, varscan2
- DSE | c.1542G>C p.K514N | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV59066666; called by muse, mutect2, varscan2
- EAPP | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as COSV51652906; called by muse, mutect2
- EDAR | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV51506554; called by muse, mutect2, varscan2
- EDNRB | c.553G>C p.E185Q (on ENST00000377211 / NM_001201397.1; = p.E95Q on NM_000115.5) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs1282405488, COSV57523073, COSV57526767; called by muse, mutect2, varscan2
- EEF2 | c.1947C>G p.I649M | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58580324, COSV58580564; called by muse, mutect2, varscan2
- EFCAB5 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV57925967; called by muse, mutect2, varscan2
- EHF | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 59/69 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV57669480; called by muse, mutect2, varscan2
- EIF2AK4 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55472703; called by muse, mutect2, varscan2
- EIF4G3 | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51690455; called by muse, mutect2, varscan2
- EIF5AL1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV73123150; called by muse, mutect2, varscan2
- ELF3 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV62837789; called by muse, mutect2, varscan2
- ELP4 | c.1003G>C p.E335Q (on ENST00000350638; = p.E334Q on NM_019040.5) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs1211889131, COSV63357034; called by muse, mutect2
- ENOSF1 | c.888G>A p.M296I (on ENST00000340116 / NM_001354066.2; = p.M248I on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV51894800; called by muse, mutect2, varscan2
- ENPP6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57071036; called by muse, mutect2, varscan2
- EPHA3 | c.1130G>T p.S377I | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV60720631; called by muse, mutect2, varscan2
- EPHB6 | c.1969C>G p.Q657E | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT tolerated (0.7); PolyPhen benign (0.12); catalogued as COSV63893115; called by muse, mutect2, varscan2
- ESPL1 | c.2638C>G p.L880V | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV57761975; called by muse, mutect2, varscan2
- ETV4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.138); catalogued as COSV60044718; called by muse, mutect2, varscan2
- EVC2 | c.2171T>A p.L724Q | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60399874; called by muse, varscan2
- EVPL | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as rs1465803613, COSV100044394; called by muse, mutect2
- F11 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as CM062626, COSV53008858; called by muse, mutect2, varscan2
- FABP12 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV64617545, COSV64617590; called by muse, mutect2, varscan2
- FAM217A | c.816G>A p.W272* | Nonsense Mutation (SNP) | VAF 32/54 reads (59%) | catalogued as COSV51162224; called by muse, mutect2, varscan2
- FAM227B | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV54814682; called by muse, mutect2
- FAM3C | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.198); catalogued as COSV63436348; called by muse, mutect2, varscan2
- FAM53A | c.1064C>G p.S355C | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100357245, COSV57402895; called by muse, mutect2
- FAM83G | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs969896084, COSV58756629, COSV58759158; called by muse, mutect2, varscan2
- FAM83H | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV62029434; called by muse, mutect2, varscan2
- FAT4 | c.4202C>T p.S1401L | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV67896141; called by muse, mutect2
- FBN2 | c.8373G>C p.Q2791H | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52536265; called by muse, mutect2, varscan2
- FCGBP | c.10708G>A p.E3570K | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1310511712; called by muse, mutect2, varscan2
- FGA | c.938C>G p.S313C | Missense Mutation (SNP) | VAF 133/282 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.43); catalogued as COSV100120105, COSV100120725, COSV57399370; called by muse, mutect2, varscan2
- FHDC1 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 123/254 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as COSV52602230, COSV52603393; called by muse, mutect2, varscan2
- FLG | c.4670C>T p.S1557L | Missense Mutation (SNP) | VAF 233/702 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as COSV64246233; called by muse, mutect2, varscan2
- FLNC | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 103/117 reads (88%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV57962094; called by muse, mutect2, varscan2
- FN1 | c.1937G>C p.R646T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV60560685; called by muse, mutect2, varscan2
- FOXJ3 | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.478); catalogued as COSV62364566; called by muse, mutect2, varscan2
- FRAS1 | c.6502G>A p.G2168R | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53635993; called by muse, mutect2, varscan2
- FRAS1 | c.8061G>C p.E2687D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99350991; called by muse, mutect2, varscan2
- FSIP2 | c.19324G>A p.D6442N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.167); catalogued as COSV58095734; called by muse, mutect2, varscan2
- GAD1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV64027189; called by muse, mutect2, varscan2
- GAD2 | c.1258C>A p.Q420K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.208); catalogued as rs778287000, COSV52165045; called by muse, mutect2, varscan2
- GALNT7 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53933614; called by muse, mutect2, varscan2
- GALNTL6 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV72490369, COSV72492753; called by muse, mutect2, varscan2
- GAPT | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 37/57 reads (65%) | catalogued as COSV100576275; called by muse, mutect2, varscan2
- GGT1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50643732; called by muse, mutect2, varscan2
- GJC3 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57210180; called by muse, mutect2, varscan2
- GMPR2 | c.1036G>C p.E346Q (on ENST00000355299 / NM_001351022.2; = p.E364Q on NM_016576.5) | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV57469877; called by muse, mutect2, varscan2
- GPATCH3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.386); catalogued as COSV64652520; called by muse, varscan2
- GPR158 | c.3463T>C p.Y1155H | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV66278795; called by muse, mutect2, varscan2
- GPR31 | c.944G>C p.R315T | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs761637610, COSV64761324, COSV64761930; called by muse, mutect2, varscan2
- GRIK4 | c.1558C>G p.L520V | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as COSV70805600; called by muse, mutect2, varscan2
- GRWD1 | c.1340G>C p.*447Sext*57 | Nonstop Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV99474349; called by muse, mutect2, varscan2
- GTF3C2 | c.1819C>T p.Q607* | Nonsense Mutation (SNP) | VAF 180/349 reads (52%) | catalogued as COSV99272647; called by muse, mutect2, varscan2
- H1-4 | c.651G>C p.K217N | Missense Mutation (SNP) | VAF 44/74 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs139391118, COSV56801628, COSV56802992; called by muse, mutect2, varscan2
- H3C2 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV52518592, COSV52519945, COSV99451484; called by muse, mutect2, varscan2
- H4C4 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV61590919, COSV61591605; called by muse, mutect2, varscan2
- HCCS | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV58239494; called by muse, mutect2, varscan2
- HHIPL2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV58566945; called by muse, mutect2, varscan2
- HIC2 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV68042718; called by muse, mutect2, varscan2
- HMCN1 | c.16270G>A p.E5424K | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as COSV54897481, COSV54907870, COSV54934854; called by muse, mutect2, varscan2
- HSPA8 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV57085551; called by muse, mutect2, varscan2
- IFT81 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 33/56 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54365551; called by muse, mutect2, varscan2
- IL3RA | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs753510585, COSV58430644; called by muse, mutect2, varscan2
- INPP1 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV59417182; called by muse, mutect2, varscan2
- INPPL1 | c.3428C>T p.S1143L | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1191053200, COSV53358412; called by muse, mutect2, varscan2
- INTS5 | c.2533C>G p.L845V | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV57953058; called by muse, mutect2, varscan2
- INTU | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 167/355 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV56541493; called by muse, mutect2, varscan2
- IRF8 | c.529T>C p.W177R | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV51899884; called by muse, mutect2, varscan2
- ITGA6 | c.800C>G p.S267C (on ENST00000442250; = p.S109C on NM_001316306.2) | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV51246552; called by muse, mutect2, varscan2
- ITGAL | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV63323663; called by muse, mutect2, varscan2
- ITGB4 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as rs762830197, COSV52330962; called by muse, mutect2, varscan2
- ITIH1 | c.2292G>A p.W764* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | catalogued as rs1450601240, COSV99835172; called by muse, mutect2, varscan2
- JRKL | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV53594977; called by muse, mutect2, varscan2
- KCNA4 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV60255026; called by muse, mutect2, varscan2
- KCNJ6 | c.24G>C p.M8I | Missense Mutation (SNP) | VAF 301/467 reads (64%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV55720219; called by muse, mutect2, varscan2
- KCNMB3 | c.258C>G p.L86= | Splice Region (SNP) | VAF 5/111 reads (5%) | catalogued as COSV58571327; called by muse, mutect2
- KDM3B | c.4552G>A p.D1518N | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV58693883; called by muse, mutect2
- KIAA1109 | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52687163; called by muse, mutect2, varscan2
- KIAA2026 | c.5773C>G p.L1925V | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV67356981; called by muse, mutect2, varscan2
- KIF13B | c.4140C>G p.I1380M | Missense Mutation (SNP) | VAF 81/93 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV72954614; called by muse, mutect2, varscan2
- KLC4 | c.1847C>G p.S616C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as COSV52438320; called by muse, mutect2, varscan2
- KLHL12 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 111/249 reads (45%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.995); catalogued as COSV66127860; called by muse, mutect2, varscan2
- KMT2D | c.12586C>T p.Q4196* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99980573; called by muse, mutect2, varscan2
- KNL1 | c.5461G>C p.D1821H (on ENST00000346991 / NM_170589.5; = p.D1795H on NM_144508.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61158891; called by muse, mutect2, varscan2
- KNTC1 | c.3295A>T p.T1099S | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV61083026; called by muse, mutect2, varscan2
- KPNA5 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV62653927; called by muse, mutect2, varscan2
- KRBA1 | c.774G>A p.V258= | Splice Region (SNP) | VAF 21/29 reads (72%) | catalogued as COSV55441672; called by muse, mutect2, varscan2
- KRT84 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57773156, COSV57773957; called by muse, mutect2, varscan2
- L2HGDH | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV55559705; called by muse, mutect2
- LAIR1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.978); catalogued as COSV100479479, COSV57309163; called by muse, mutect2
- LARP7 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60521993; called by muse, mutect2, varscan2
- LGSN | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV65728153; called by muse, mutect2, varscan2
- LILRA1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 122/222 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs760878213, COSV52180445; called by muse, mutect2, varscan2
- LILRA5 | c.414C>G p.F138L | Missense Mutation (SNP) | VAF 59/114 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV56644660; called by muse, mutect2, varscan2
- LILRB3 | c.1918C>G p.L640V (on ENST00000346401; = p.L628V on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs142108207, COSV54437250; called by muse, mutect2, varscan2
- LRP1 | c.5104G>C p.E1702Q | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs141183147; called by muse, mutect2, varscan2
- LRP1 | c.12752C>G p.S4251C | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV54521260; called by muse, mutect2, varscan2
- LRP1B | c.13279G>A p.E4427K | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV67259304; called by muse, mutect2, varscan2
- LRRC37A3 | c.3397G>T p.D1133Y | Missense Mutation (SNP) | VAF 138/250 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV58535039, COSV58536353; called by muse, varscan2
- LRRC37A3 | c.3280G>C p.D1094H | Missense Mutation (SNP) | VAF 218/372 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58536361; called by muse, varscan2
- LRRC41 | c.1484T>A p.L495H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58441656; called by muse, mutect2
- LRRC7 | c.1753G>A p.A585T (on ENST00000651989 / NM_001370785.2; = p.A552T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV50561984; called by muse, mutect2, varscan2
- LTB | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53002261; called by muse, mutect2, varscan2
- LTBP1 | c.1988C>G p.S663* (on ENST00000404816 / NM_206943.4; = p.S337* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 32/65 reads (49%) | catalogued as COSV100616964; called by muse, mutect2, varscan2
- MAGED1 | c.196C>G p.Q66E | Missense Mutation (SNP) | VAF 18/19 reads (95%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); catalogued as rs782161142, COSV58516107, COSV58516397; called by muse, mutect2, varscan2
- MAGI1 | c.1494C>G p.I498M | Missense Mutation (SNP) | VAF 83/156 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58338961; called by muse, mutect2, varscan2
- MAN2C1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as COSV99145347; called by muse, mutect2, varscan2
- MAPK10 | c.431C>T p.S144F (on ENST00000359221 / NM_001351625.2; = p.S182F on NM_002753.5) | Missense Mutation (SNP) | VAF 83/167 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV60374734, COSV60390767; called by muse, mutect2, varscan2
- MAPK13 | c.792G>T p.Q264H | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52984465; called by muse, varscan2
- MAPKAPK3 | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 58/120 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV63598134; called by muse, mutect2, varscan2
- MARK2 | c.2251G>T p.E751* (on ENST00000402010 / NM_001039469.2; = p.E687* on NM_004954.5) | Nonsense Mutation (SNP) | VAF 73/145 reads (50%) | catalogued as COSV100036165; called by muse, mutect2, varscan2
- MAT2A | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.344); catalogued as COSV52089847; called by muse, mutect2, varscan2
- MCM9 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV60164889, COSV60165062; called by muse, mutect2, varscan2
- MECOM | c.-191C>G | Splice Region (SNP) | VAF 43/72 reads (60%) | catalogued as COSV52971562; called by muse, mutect2, varscan2
- MICAL2 | c.3211G>A p.E1071K | Missense Mutation (SNP) | VAF 52/67 reads (78%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.073); catalogued as COSV56324180; called by muse, mutect2, varscan2
- MINDY4 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV54677347; called by muse, mutect2, varscan2
- MRPS36 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 36/69 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV56508387; called by muse, mutect2, varscan2
- MS4A5 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV55741586; called by muse, mutect2, varscan2
- MSL1 | c.1085C>T p.S362F (on ENST00000398532 / NM_001365919.1; = p.S99F on NM_001012241.2) | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.578); catalogued as rs1449526305, COSV59899612; called by muse, mutect2, varscan2
- MUC16 | c.19910C>G p.S6637C | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as rs1169453595, COSV67484243; called by muse, mutect2, varscan2
- MUC5B | c.13871C>T p.T4624I | Missense Mutation (SNP) | VAF 45/50 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV71594557; called by muse, mutect2, varscan2
- MZF1 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 18/25 reads (72%) | catalogued as COSV99285182; called by muse, mutect2, varscan2
- MZT2A | c.396G>C p.Q132H | Missense Mutation (SNP) | VAF 76/106 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1559354449, COSV58312923; called by muse, mutect2, varscan2
- NAA40 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV58161720; called by muse, mutect2, varscan2
- NANOG | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs1306599242; called by muse, mutect2, varscan2
- NAP1L1 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV53875816; called by muse, mutect2
- NAV3 | c.6452A>G p.Y2151C (on ENST00000397909 / NM_001024383.2; = p.Y2129C on NM_014903.6) | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57103438; called by muse, mutect2, varscan2
- NCOA7 | c.2299G>C p.D767H | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); catalogued as COSV57658572; called by muse, mutect2, varscan2
- NDUFS1 | c.2143A>G p.T715A | Missense Mutation (SNP) | VAF 73/110 reads (66%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV51912609; called by muse, mutect2, varscan2
- NECAB1 | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV70243140; called by muse, mutect2
- NF1 | c.3233C>A p.S1078* | Nonsense Mutation (SNP) | VAF 22/42 reads (52%) | catalogued as COSV100646750, COSV62219702; called by muse, mutect2, varscan2
- NFKB1 | c.1669C>G p.Q557E (on ENST00000394820 / NM_001382627.1; = p.Q558E on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV56959937; called by muse, mutect2, varscan2
- NFXL1 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV61199996, COSV61200203; called by muse, mutect2, varscan2
- NID2 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as COSV53501036; called by muse, mutect2, varscan2
- NKAPL | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV59198848; called by muse, mutect2, varscan2
- NPBWR2 | c.165C>G p.I55M | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV63900106, COSV63900486; called by muse, mutect2, varscan2
- NPR3 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as COSV54091810; called by muse, mutect2, varscan2
- NPY1R | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV99648687; called by muse, mutect2, varscan2
- NR2C2 | c.1025G>A p.S342N (on ENST00000393102; = p.S361N on NM_003298.5) | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs377462232; called by muse, mutect2, varscan2
- NSD1 | c.2363G>C p.R788P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as CD035625, COSV61781928; called by muse, mutect2, varscan2
- NTM | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as COSV66189302; called by muse, mutect2, varscan2
- NTNG2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.898); catalogued as COSV62368309; called by muse, mutect2, varscan2
- NUP155 | c.2081A>T p.E694V (on ENST00000231498 / NM_153485.3; = p.E635V on NM_004298.4) | Missense Mutation (SNP) | VAF 74/137 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV51533368; called by muse, mutect2, varscan2
- NUP155 | c.2080G>C p.E694Q (on ENST00000231498 / NM_153485.3; = p.E635Q on NM_004298.4) | Missense Mutation (SNP) | VAF 78/143 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV51533378; called by muse, mutect2, varscan2
- NUP93 | c.2060C>T p.S687F | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV57432997; called by muse, mutect2, varscan2
- NXF3 | c.843C>G p.D281E | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as COSV67704780; called by muse, mutect2, varscan2
- OPRL1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs138440707; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- OR8K5 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100537295, COSV57888322, COSV57890208; called by muse, mutect2, varscan2
- OSMR | c.887G>T p.W296L | Missense Mutation (SNP) | VAF 83/137 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57089951; called by muse, mutect2, varscan2
- PAK1IP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV52584469, COSV99468416, COSV99468494; called by muse, mutect2, varscan2
- PARP14 | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as rs1415440106, COSV101506265, COSV101506274; called by muse, mutect2, varscan2
- PARP9 | c.603G>C p.W201C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64451508; called by muse, mutect2, varscan2
- PBX2 | c.1256A>G p.E419G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV100903993; called by muse, mutect2, varscan2
- PCDH8 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58814506; called by muse, mutect2, varscan2
- PCDHB1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60632716; called by muse, mutect2, varscan2
- PCDHB4 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.419); catalogued as COSV52025655; called by muse, mutect2, varscan2
- PCDHB9 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as rs782272485, COSV53378001; called by muse, mutect2, varscan2
- PCDHGA9 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV54006375, COSV54058343, COSV99532223; called by muse, mutect2, varscan2
- PCDHGA9 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV54006385; called by muse, mutect2, varscan2
- PCNX1 | c.5638G>A p.E1880K | Missense Mutation (SNP) | VAF 61/71 reads (86%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV53099666; called by muse, mutect2, varscan2
- PCNX2 | c.5915C>T p.S1972L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV50854325; called by muse, mutect2, varscan2
- PCNX4 | c.739A>T p.I247F (on ENST00000406854 / NM_001330177.2; = p.I13F on NM_022495.5) | Missense Mutation (SNP) | VAF 99/123 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV58307011; called by muse, mutect2, varscan2
- PDCD6IP | c.2572C>G p.Q858E | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.9); catalogued as COSV56244836; called by muse, mutect2, varscan2
- PDE4DIP | c.6187C>T p.Q2063* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100518729, COSV100521091; called by mutect2, varscan2
- PFDN6 | c.345C>G p.F115L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV65842806; called by muse, mutect2, varscan2
- PIK3CB | c.1762G>A p.V588I | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.812); catalogued as COSV56688944; called by muse, mutect2, varscan2
- PIM1 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1222607867, COSV65166376; called by muse, mutect2, varscan2
- PLEKHG3 | c.1138G>A p.E380K (on ENST00000394691; = p.E436K on NM_001308147.2) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV55982675; called by muse, mutect2, varscan2
- PLEKHM2 | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101009091; called by muse, mutect2, varscan2
- PLSCR2 | c.450G>C p.L150F (on ENST00000497985 / NM_001199978.1; = p.L77F on NM_020359.2) | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV60863502; called by muse, mutect2, varscan2
- POLQ | c.2272T>C p.Y758H | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51758800; called by muse, mutect2, varscan2
- POLRMT | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 89/183 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV74056314; called by muse, mutect2, varscan2
- PPFIA2 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100332936, COSV100333353; called by muse, mutect2, varscan2
- PPIB | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 157/276 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55520999; called by muse, mutect2, varscan2
- PPIG | c.68G>A p.R23K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53645189; called by muse, mutect2
- PPL | c.4900G>A p.D1634N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as rs753840909, COSV52171278; called by muse, mutect2, varscan2
- PPL | c.4551G>C p.Q1517H | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV52171287; called by muse, mutect2, varscan2
- PPP1R15A | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 205/382 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs755786656, COSV52340027; called by muse, mutect2, varscan2
- PRKD1 | c.413C>G p.T138S | Missense Mutation (SNP) | VAF 60/71 reads (85%) | SIFT tolerated (0.27); PolyPhen benign (0.041); catalogued as COSV59580505; called by muse, mutect2, varscan2
- PRORP | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 34/43 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51622043, COSV99156624; called by muse, mutect2, varscan2
- PRPF18 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV60726023; called by muse, mutect2, varscan2
- PRRG2 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 114/192 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV55871095; called by muse, mutect2, varscan2
- PRTG | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV66839892; called by muse, mutect2, varscan2
- PSD | c.1693C>A p.L565M | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50054511; called by muse, mutect2, varscan2
- PSIP1 | c.278C>G p.S93* | Nonsense Mutation (SNP) | VAF 12/13 reads (92%) | catalogued as COSV101050928; called by muse, mutect2, varscan2
- PTGR2 | c.925G>C p.E309Q | Missense Mutation (SNP) | VAF 51/69 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1302609772, COSV50866706; called by muse, mutect2, varscan2
- PYHIN1 | c.949C>G p.L317V | Missense Mutation (SNP) | VAF 68/100 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV63723587; called by muse, mutect2, varscan2
- QPRT | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 129/201 reads (64%) | SIFT tolerated (0.24); PolyPhen benign (0.114); catalogued as rs772960109, COSV54879662, COSV54880088; called by muse, mutect2, varscan2
- RAB42 | c.299C>A p.S100* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100866080; called by muse, mutect2, varscan2
- RABEPK | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV52337606; called by muse, mutect2, varscan2
- RALGAPA1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51892992; called by muse, mutect2, varscan2
- RARS1 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs757193866, COSV51564915; called by muse, mutect2, varscan2
- RASD2 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.395); catalogued as COSV53353283; called by muse, mutect2, varscan2
- RBKS | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56223603; called by muse, mutect2, varscan2
- RBM7 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV64955591, COSV64955880; called by muse, mutect2
- RESF1 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV57024683; called by muse, mutect2
- RGS12 | c.3509C>T p.S1170F | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV58755623; called by muse, mutect2, varscan2
- RHOU | c.479G>C p.G160A | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64208936; called by muse, mutect2
- RLF | c.3047C>G p.S1016* | Nonsense Mutation (SNP) | VAF 97/145 reads (67%) | catalogued as COSV101035283; called by muse, mutect2, varscan2
- RLF | c.3299C>T p.S1100L | Missense Mutation (SNP) | VAF 144/211 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV65652800; called by muse, mutect2, varscan2
- RNF157 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53947384; called by muse, mutect2
- RNF17 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV55041907, COSV99691998; called by muse, mutect2, varscan2
- RNF213 | c.5857C>T p.Q1953* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV100300387, COSV60393415; called by muse, mutect2, varscan2
- RNF216 | c.2001G>C p.M667I (on ENST00000425013 / NM_207116.3; = p.M724I on NM_207111.4) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV66292143; called by muse, mutect2, varscan2
- RSBN1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV54734489; called by muse, mutect2, varscan2
- RSC1A1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV60780862; called by muse, mutect2, varscan2
- RYR2 | c.8978G>A p.G2993E | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV63705359; called by muse, mutect2, varscan2
- RYR3 | c.3687G>A p.M1229I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV66804112; called by muse, mutect2, varscan2
- SCAF1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.103); catalogued as COSV100862133; called by muse, mutect2, varscan2
- SCARB1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 14/20 reads (70%) | catalogued as COSV99909179; called by muse, mutect2, varscan2
- SCMH1 | c.562A>T p.T188S (on ENST00000326197 / NM_001031694.2; = p.T141S on NM_012236.4) | Missense Mutation (SNP) | VAF 78/124 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV58238602; called by muse, mutect2, varscan2
- SCN10A | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV101479366, COSV71860946; called by muse, mutect2, varscan2
- SCYL3 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 86/149 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV63047358; called by muse, mutect2, varscan2
- SEC14L4 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV55400958, COSV55401094; called by muse, mutect2
- SEMA3E | c.2305C>T p.P769S | Missense Mutation (SNP) | VAF 113/226 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57103594; called by muse, mutect2, varscan2
- SEPTIN4 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); catalogued as COSV58728797; called by muse, mutect2, varscan2
- SGIP1 | c.808G>C p.G270R | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.394); catalogued as COSV52776173; called by muse, mutect2, varscan2
- SH2B3 | c.1361G>A p.C454Y | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV57985601; called by muse, mutect2, varscan2
- SHCBP1L | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV62356442; called by muse, mutect2, varscan2
- SHOX | c.506G>A p.R169K | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as CM134681, COSV61862013; called by muse, mutect2, varscan2
- SLC44A3 | c.250C>G p.L84V (on ENST00000271227 / NM_001114106.3; = p.L36V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54733001; called by muse, varscan2
- SLC6A6 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 50/129 reads (39%) | catalogued as COSV100692103; called by muse, mutect2, varscan2
- SLC9C2 | c.1804C>G p.H602D | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV100876711; called by muse, mutect2
- SLCO1A2 | c.171del p.V58Lfs*15 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | catalogued as COSV56608267; called by mutect2, pindel, varscan2
- SLU7 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.474); catalogued as COSV51789615; called by muse, mutect2
- SMC3 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV62421687; called by muse, mutect2, varscan2
- SMC6 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61172081; called by muse, mutect2, varscan2
- SMPD4 | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 4/19 reads (21%) | catalogued as COSV60082141; called by muse, mutect2, varscan2
- SNX6 | c.337G>C p.D113H (on ENST00000652385; = p.D101H on NM_152233.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61919929; called by muse, mutect2, varscan2
- SOX17 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52027395; called by muse, mutect2, varscan2
- SPRYD3 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 81/128 reads (63%) | catalogued as COSV100036688; called by muse, mutect2, varscan2
- SREBF1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 58/61 reads (95%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); catalogued as COSV55418854; called by muse, mutect2, varscan2
- SREK1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 45/150 reads (30%) | catalogued as COSV52331740; called by muse, mutect2, varscan2
- SRL | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.225); catalogued as COSV68424098; called by muse, mutect2
- SRRM4 | c.1073C>G p.S358* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99938343; called by muse, mutect2
- SSH2 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV52178848; called by muse, mutect2
- ST6GALNAC1 | c.130A>C p.R44= | Splice Region (SNP) | VAF 14/37 reads (38%) | catalogued as COSV50078478; called by muse, mutect2, varscan2
- STK3 | c.1279G>C p.D427H | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.416); catalogued as rs762318051, COSV69226142; called by muse, mutect2, varscan2
- STK31 | c.749C>G p.S250* | Nonsense Mutation (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100669309, COSV99054355; called by muse, mutect2
- STK31 | c.3044C>G p.A1015G | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV63458597; called by muse, mutect2, varscan2
- STON1 | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59135731; called by muse, mutect2, varscan2
- STRN | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV55751051; called by muse, mutect2, varscan2
- STX1A | c.609C>G p.I203M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.025); catalogued as COSV56095953; called by muse, mutect2, varscan2
- SYNE1 | c.23921G>C p.R7974T (on ENST00000367255 / NM_182961.4; = p.R7903T on NM_033071.3) | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55066055; called by muse, mutect2, varscan2
- SYNE1 | c.19603G>C p.E6535Q (on ENST00000367255 / NM_182961.4; = p.E6464Q on NM_033071.3) | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV54928392, COSV55066112, COSV55102638; called by muse, mutect2, varscan2
- SYNE1 | c.2123G>A p.R708K (on ENST00000367255 / NM_182961.4; = p.R715K on NM_033071.3) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55066161; called by muse, mutect2, varscan2
- SYTL3 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1259385366, COSV51913809; called by muse, mutect2, varscan2
- TAC3 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs763197085, COSV55648662; called by muse, mutect2, varscan2
- TACR3 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.023); catalogued as rs1174837760, COSV59206693; called by muse, mutect2, varscan2
- TBC1D1 | c.3193C>T p.Q1065* | Nonsense Mutation (SNP) | VAF 47/99 reads (47%) | catalogued as COSV99791055; called by muse, mutect2, varscan2
- TBC1D8B | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 51/56 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV52182323; called by muse, mutect2, varscan2
- TCEA2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs767883408, COSV58657657; called by muse, mutect2, varscan2
- TEX14 | c.1513G>C p.D505H (on ENST00000240361 / NM_001201457.2; = p.D499H on NM_031272.5) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53623939; called by muse, mutect2, varscan2
- THAP4 | c.1549G>C p.E517Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.23); catalogued as COSV58710309; called by muse, mutect2, varscan2
- THRSP | c.71T>C p.V24A | Missense Mutation (SNP) | VAF 36/821 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV55246743; called by muse, mutect2
- THSD7A | c.4393G>C p.E1465Q | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV70270172; called by muse, mutect2, varscan2
- TLE5 | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55592636; called by muse, mutect2
- TLR6 | c.1703G>C p.R568T | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV67935628; called by muse, mutect2, varscan2
- TMCO4 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2, varscan2
- TMEM108 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.136); catalogued as COSV58879442; called by muse, mutect2, varscan2
- TMEM38A | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV51820366; called by muse, mutect2, varscan2
- TNK1 | c.1422G>C p.K474N (on ENST00000576812 / NM_001251902.2; = p.K469N on NM_003985.5) | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV61171759; called by muse, mutect2, varscan2
- TNN | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV53432972; called by muse, mutect2, varscan2
- TP53INP1 | c.282G>C p.E94D | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61332937; called by muse, mutect2, varscan2
- TP53INP1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.329); catalogued as COSV61332952; called by muse, mutect2, varscan2
- TPD52L1 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59193280; called by muse, mutect2, varscan2
- TRAK1 | c.1888G>A p.E630K (on ENST00000327628 / NM_001349247.2; = p.E572K on NM_014965.5) | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as rs1417907503, COSV58262633; called by muse, mutect2
- TRAPPC2L | c.52C>A p.R18S | Missense Mutation (SNP) | VAF 122/241 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.312); catalogued as COSV51939612; called by muse, mutect2, varscan2
- TRIM11 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs752798123, COSV52859406; called by muse, mutect2, varscan2
- TRIO | c.4032G>T p.M1344I | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as rs1469154563, COSV100710263; called by muse, mutect2
- TRMT1 | c.11C>G p.S4W | Missense Mutation (SNP) | VAF 53/94 reads (56%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); catalogued as COSV52835550; called by muse, mutect2, varscan2
- TRRAP | c.7066G>A p.E2356K (on ENST00000359863 / NM_001244580.1; = p.E2338K on NM_003496.3) | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV62839467; called by muse, mutect2, varscan2
- TSHZ2 | c.1415C>A p.T472N | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61590589; called by muse, mutect2, varscan2
- TSPAN12 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 94/109 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV56079803; called by muse, mutect2, varscan2
- TSPYL1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as COSV63994254; called by muse, mutect2, varscan2
- TTC3 | c.5653G>A p.E1885K | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV61294633; called by muse, mutect2, varscan2
- TTI1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 91/276 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as COSV65062570; called by muse, mutect2, varscan2
- TTLL3 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV59615343; called by muse, mutect2, varscan2
- TTN | c.69618G>C p.E23206D (on ENST00000591111; = p.E15782D on NM_003319.4) | Missense Mutation (SNP) | VAF 25/35 reads (71%) | PolyPhen probably damaging (0.99); catalogued as COSV100599046, COSV60261309; called by muse, mutect2, varscan2
- TTPAL | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52829544; called by muse, mutect2, varscan2
- TTPAL | c.1019C>G p.S340C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV52829547; called by muse, mutect2, varscan2
- TTYH2 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.123); catalogued as COSV53912727; called by muse, mutect2, varscan2
- TXNDC16 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs141505627; called by mutect2, varscan2
- UBA6 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs373643001; called by muse, mutect2, varscan2
- UBAP2 | c.1959G>C p.Q653H | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.22); PolyPhen benign (0.035); catalogued as COSV62548374; called by muse, mutect2, varscan2
- UBE2S | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as rs1299385628, COSV52741157; called by muse, mutect2, varscan2
- UGGT2 | c.4127G>A p.G1376E | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65073445, COSV65078069; called by muse, mutect2
- USP24 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53775303; called by muse, mutect2, varscan2
- USP4 | c.2464G>C p.V822L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV55539649; called by muse, mutect2, varscan2
- UTY | c.1304G>C p.R435T | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV58871578; called by muse, mutect2, varscan2
- VWF | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 45/71 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54630513; called by muse, mutect2, varscan2
- WDCP | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 94/146 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV54592516; called by muse, mutect2, varscan2
- WDFY3 | c.9247C>G p.L3083V | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV55710738; called by muse, mutect2, varscan2
- WDR17 | c.2902C>T p.L968F | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54580745; called by muse, mutect2, varscan2
- WDR46 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV65842798; called by muse, mutect2, varscan2
- XAGE5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 42/43 reads (98%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV63568158; called by muse, mutect2, varscan2
- XDH | c.2628G>C p.Q876H | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV65150595; called by muse, mutect2, varscan2
- ZBED6CL | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV59604743, COSV59605240; called by muse, mutect2
- ZBTB17 | c.1822C>T p.H608Y | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs878869459, COSV65271240; called by muse, mutect2, varscan2
- ZBTB22 | c.1566C>G p.F522L | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV56470425, COSV56471856; called by muse, mutect2, varscan2
- ZBTB22 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56471860; called by muse, mutect2, varscan2
- ZBTB24 | c.718G>C p.D240H | Missense Mutation (SNP) | VAF 147/251 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57783023; called by muse, mutect2, varscan2
- ZC3HAV1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 14/290 reads (5%) | catalogued as COSV99648474; called by muse, mutect2
- ZFHX4 | c.2336C>A p.A779D | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV50924910, COSV51486460, COSV99266984; called by muse, mutect2, varscan2
- ZFP3 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100603744; called by muse, mutect2, varscan2
- ZFY | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV50083858; called by muse, mutect2, varscan2
- ZMYM4 | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100110209; called by muse, mutect2
- ZNF100 | c.1513A>G p.I505V | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV59749368; called by muse, mutect2, varscan2
- ZNF14 | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 79/122 reads (65%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.594); catalogued as rs751590829, COSV59850860; called by muse, mutect2, varscan2
- ZNF165 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 115/187 reads (61%) | catalogued as COSV66102770; called by muse, mutect2, varscan2
- ZNF330 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 72/135 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53708111; called by muse, mutect2, varscan2
- ZNF331 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267605657, COSV53479031; called by muse, mutect2, varscan2
- ZNF343 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV53855169; called by muse, mutect2, varscan2
- ZNF350 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV54710163; called by muse, mutect2, varscan2
- ZNF350 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 73/119 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV54710175; called by muse, mutect2, varscan2
- ZNF397 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.995); catalogued as COSV54352237; called by muse, mutect2, varscan2
- ZNF43 | c.2099A>T p.H700L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV61685320; called by muse, mutect2, varscan2
- ZNF513 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.232); catalogued as rs374112566; called by muse, mutect2, varscan2
- ZNF70 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.652); catalogued as COSV59533605; called by muse, mutect2
- ZNF700 | c.1468C>G p.Q490E | Missense Mutation (SNP) | VAF 96/150 reads (64%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.523); catalogued as COSV54314692; called by muse, mutect2, varscan2
- ZNF875 | c.1763T>C p.F588S | Missense Mutation (SNP) | VAF 56/107 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60993045; called by muse, mutect2, varscan2
- ATP2A2 | c.1602del p.P535Lfs*2 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2170G>C p.D724H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DCTN4 | c.524del p.P175Lfs*40 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- HDAC9 | c.3065del p.G1022Afs*22 (on ENST00000441542 / NM_178425.3; = p.G1019Afs*22 on NM_178423.3) | Frame Shift Del (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- IGLV2-8 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 119/429 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIR3DL2 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 157/279 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PPARG | c.58dup p.T20Nfs*14 | Frame Shift Ins (INS) | VAF 37/106 reads (35%) | called by mutect2, pindel, varscan2
- ABCA7 | c.2805G>A p.V935= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV54035340; called by muse, mutect2, varscan2
- ABCC11 | c.3423C>T p.I1141= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV62325170; called by muse, mutect2, varscan2
- ABHD16A | c.1225C>T p.L409= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as COSV65452344; called by muse, mutect2, varscan2
- ACP3 | c.1173G>A p.L391= | Silent (SNP) | VAF 86/342 reads (25%) | catalogued as COSV63640806; called by muse, mutect2, varscan2
- ADCY2 | c.15G>A p.A5= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV100602608; called by muse, mutect2, varscan2
- ADD1 | c.1200G>A p.L400= | Silent (SNP) | VAF 57/149 reads (38%) | catalogued as COSV53272888, COSV99296743; called by muse, mutect2, varscan2
- AKAP11 | c.5010C>T p.S1670= | Silent (SNP) | VAF 30/50 reads (60%) | catalogued as COSV50299935; called by muse, mutect2, varscan2
- AKAP4 | c.1887C>T p.I629= | Silent (SNP) | VAF 94/118 reads (80%) | catalogued as rs1161069834, COSV62073883; called by muse, mutect2, varscan2
- AL592490.1 | c.483G>A p.A161= | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as COSV69427321, COSV69427375; called by muse, mutect2, varscan2
- ALPI | c.165C>T p.L55= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV55015768; called by muse, mutect2, varscan2
- ALPK1 | c.2607C>T p.H869= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as rs553837857, COSV51589956; called by muse, mutect2, varscan2
- AOAH | c.435G>A p.K145= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV51738157, COSV51748377; called by muse, mutect2, varscan2
- APC | c.3261C>G p.L1087= | Silent (SNP) | VAF 23/209 reads (11%) | catalogued as COSV57364823, COSV57369606; called by muse, mutect2, varscan2
- ARHGEF19 | c.477C>T p.F159= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV54618081; called by muse, mutect2, varscan2
- ARMC3 | c.1662G>A p.L554= | Silent (SNP) | VAF 61/143 reads (43%) | catalogued as COSV53065708; called by muse, mutect2, varscan2
- ARMC8 | c.762C>T p.L254= (on ENST00000469044 / NM_001363941.2; = p.L240= on NM_014154.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as COSV61769248; called by muse, mutect2, varscan2
- ARSI | c.1392C>T p.L464= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV60818141; called by muse, mutect2
- ASIC4 | c.279G>A p.L93= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs368212523; called by muse, mutect2, varscan2
- ATF4 | c.894G>A p.K298= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1229616375, COSV100307642; called by muse, mutect2, varscan2
- ATM | c.4302G>A p.K1434= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as rs876658751, COSV53765473; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP8B3 | c.1656C>T p.L552= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs375560334; called by muse, mutect2, varscan2
- AVEN | c.576C>G p.L192= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV60736746; called by muse, mutect2, varscan2
- BCAR1 | c.558G>C p.G186= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV50797361; called by muse, mutect2, varscan2
- BICD1 | c.1434G>A p.E478= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV55685557; called by muse, mutect2, varscan2
- C2orf78 | c.276C>G p.L92= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV101280873, COSV68518847; called by muse, mutect2, varscan2
- C4B | c.3837A>C p.A1279= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV70313649; called by muse, mutect2, varscan2
- C4BPB | c.726G>T p.L242= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as COSV54692220, COSV54692430; called by muse, mutect2, varscan2
- C8orf76 | c.1095C>T p.F365= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV52689778, COSV52691677; called by muse, mutect2
- CALCRL | c.1183C>T p.L395= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV66476655; called by muse, mutect2, varscan2
- CAPN1 | c.2079C>T p.D693= | Silent (SNP) | VAF 7/164 reads (4%) | catalogued as COSV54198827, COSV54199386; called by muse, mutect2
- CCR9 | c.987G>A p.V329= (on ENST00000357632 / NM_031200.3; = p.V317= on NM_006641.4) | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV62940636; called by muse, mutect2, varscan2
- CDH4 | c.2295G>A p.T765= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs761908460, COSV64640909; called by muse, mutect2, varscan2
- CFAP47 | c.1656A>G p.A552= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV52889917; called by muse, mutect2, varscan2
- CHAF1A | c.318C>T p.I106= | Silent (SNP) | VAF 124/350 reads (35%) | catalogued as rs759026569, COSV56672009; called by muse, mutect2, varscan2
- CLHC1 | c.1644G>A p.Q548= | Silent (SNP) | VAF 51/76 reads (67%) | catalogued as COSV68464128, COSV68464809; called by muse, mutect2, varscan2
- CNNM2 | c.852G>C p.P284= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV63996338; called by muse, mutect2, varscan2
- COL12A1 | c.9102C>T p.I3034= | Silent (SNP) | VAF 67/110 reads (61%) | catalogued as COSV59404338; called by muse, mutect2, varscan2
- CPAMD8 | c.3462C>T p.V1154= (on ENST00000651564; = p.V1107= on NM_015692.5) | Silent (SNP) | VAF 88/154 reads (57%) | catalogued as COSV71597206; called by muse, mutect2, varscan2
- DBNL | c.156G>A p.E52= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV101289360; called by muse, mutect2
- DCLK2 | c.2067C>T p.V689= | Silent (SNP) | VAF 10/187 reads (5%) | catalogued as rs1245727726, COSV56204177, COSV56209831; called by muse, mutect2
- DERA | c.843G>A p.L281= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs372112499; called by muse, mutect2, varscan2
- DNAH7 | c.7185C>G p.V2395= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV56779479; called by muse, mutect2, varscan2
- DNAJB12 | c.852G>A p.L284= (on ENST00000338820; = p.L250= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as COSV58761346; called by muse, mutect2, varscan2
- DROSHA | c.426C>T p.F142= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60780652; called by muse, mutect2, varscan2
- DYNLL2 | c.48C>T p.D16= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs752955281, COSV73897065; called by muse, mutect2, varscan2
- EMC8 | c.399G>T p.T133= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV53667665, COSV53668194; called by muse, mutect2, varscan2
- EPB41L1 | c.1353C>T p.D451= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs1232516207, COSV52442511; called by muse, mutect2, varscan2
- EPO | c.525C>T p.F175= | Silent (SNP) | VAF 105/311 reads (34%) | catalogued as COSV53161577; called by muse, mutect2, varscan2
- FARS2 | c.18C>T p.L6= | Silent (SNP) | VAF 55/89 reads (62%) | catalogued as COSV51165115, COSV51172845; called by muse, mutect2, varscan2
- FBXO22 | c.888C>G p.V296= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV57618451; called by muse, mutect2, varscan2
- FCGBP | c.6054G>A p.A2018= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs1404184566, COSV99662005; called by muse, mutect2, varscan2
- FMO1 | c.417C>T p.I139= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as COSV100707683, COSV61447270; called by muse, mutect2, varscan2
- FOXS1 | c.369C>T p.T123= | Silent (SNP) | VAF 51/69 reads (74%) | catalogued as COSV54067041, COSV54067777; called by muse, mutect2, varscan2
- GBX2 | c.576G>A p.P192= | Silent (SNP) | VAF 80/143 reads (56%) | catalogued as rs757987864, COSV60444902; called by muse, mutect2, varscan2
- GOPC | c.1366C>T p.L456= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs758656022, COSV50003672; called by muse, mutect2, varscan2
- GPATCH3 | c.1038G>A p.Q346= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as COSV64652523; called by muse, mutect2, varscan2
- GPBAR1 | c.519C>A p.L173= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV50309164; called by muse, mutect2, varscan2
- GPRC6A | c.1926C>G p.L642= | Silent (SNP) | VAF 57/95 reads (60%) | catalogued as COSV59955214; called by muse, mutect2, varscan2
- GRB10 | c.1359C>T p.S453= (on ENST00000398812; = p.S407= on NM_001001549.3) | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs1001553225, COSV60011524; called by muse, mutect2, varscan2
- GRID2 | c.2463G>A p.Q821= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as COSV56246882; called by muse, mutect2, varscan2
- GRIN3A | c.1212C>T p.T404= | Silent (SNP) | VAF 67/77 reads (87%) | catalogued as COSV62457046, COSV62459494; called by muse, mutect2, varscan2
- GRM4 | c.2469G>T p.T823= | Silent (SNP) | VAF 81/140 reads (58%) | catalogued as rs538220499, COSV65217700; called by muse, mutect2, varscan2
- GRM4 | c.60C>T p.L20= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as COSV65217723; called by muse, mutect2, varscan2
- GSTM2 | c.219C>T p.S73= | Silent (SNP) | VAF 144/271 reads (53%) | catalogued as COSV53983618; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2427C>G p.L809= (on ENST00000265755 / NM_016328.3; = p.L794= on NM_005685.4) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV56090510; called by muse, mutect2, varscan2
- H2BC5 | c.222C>T p.I74= | Silent (SNP) | VAF 105/184 reads (57%) | catalogued as rs1358692800, COSV56800766, COSV56803159, COSV99175306; called by muse, varscan2
- HCRTR2 | c.468C>T p.I156= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV63794015, COSV63798243; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.1050G>A p.R350= (on ENST00000354667 / NM_031243.3; = p.R338= on NM_002137.4) | Silent (SNP) | VAF 50/213 reads (23%) | catalogued as COSV61160706; called by muse, mutect2, varscan2
- HSPA9 | c.1863C>G p.L621= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV51865809; called by muse, mutect2
- IHO1 | c.195G>A p.L65= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV56509463; called by muse, mutect2, varscan2
- IL27RA | c.27C>T p.F9= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs773057097, COSV54602387; called by muse, mutect2, varscan2
- IRS1 | c.2076G>C p.G692= | Silent (SNP) | VAF 40/86 reads (47%) | catalogued as rs573173199, COSV59338877; called by muse, varscan2
- KANK1 | c.2892C>T p.L964= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV63214384; called by muse, mutect2, varscan2
- KARS1 | c.1548C>A p.A516= | Silent (SNP) | VAF 37/159 reads (23%) | catalogued as COSV56693829; called by muse, mutect2, varscan2
- KCNH7 | c.1494G>A p.L498= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as COSV59808574; called by muse, mutect2, varscan2
- KIF21B | c.2286G>C p.L762= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as COSV59763710; called by muse, mutect2, varscan2
- KIFBP | c.1557C>G p.L519= | Silent (SNP) | VAF 63/127 reads (50%) | catalogued as COSV62832248; called by muse, mutect2, varscan2
- KIFC2 | c.1164C>T p.L388= | Silent (SNP) | VAF 30/44 reads (68%) | catalogued as rs1179126146, COSV56761002; called by muse, mutect2, varscan2
- KLHL9 | c.750C>T p.L250= | Silent (SNP) | VAF 5/82 reads (6%) | catalogued as COSV62922324; called by muse, mutect2
- KLK7 | c.459G>A p.T153= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs141002495; called by muse, mutect2, varscan2
- LAMC3 | c.2940C>T p.N980= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs940847303, COSV63088518; called by muse, mutect2, varscan2
- LETM1 | c.552C>G p.R184= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV57103523; called by muse, mutect2, varscan2
- LIG3 | c.1491G>A p.K497= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as COSV52006368; called by muse, mutect2, varscan2
- LRRK2 | c.5829G>C p.R1943= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV54165156; called by muse, mutect2, varscan2
- MAN2B2 | c.1878G>A p.V626= | Silent (SNP) | VAF 29/52 reads (56%) | catalogued as COSV53453140; called by muse, mutect2, varscan2
- MAP3K9 | c.585C>T p.F195= | Silent (SNP) | VAF 78/97 reads (80%) | catalogued as rs371140481; called by muse, mutect2, varscan2
- MCM4 | c.342G>A p.Q114= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV50629867; called by muse, mutect2, varscan2
- MTMR12 | c.2106C>G p.L702= | Silent (SNP) | VAF 111/202 reads (55%) | catalogued as rs1352964290, COSV53786707; called by muse, mutect2, varscan2
- MYBPC2 | c.2946C>G p.V982= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MYRF | c.936C>T p.L312= (on ENST00000278836 / NM_001127392.3; = p.L303= on NM_013279.4) | Silent (SNP) | VAF 107/209 reads (51%) | catalogued as COSV53892502; called by muse, mutect2, varscan2
- NADSYN1 | c.921C>T p.L307= | Silent (SNP) | VAF 30/35 reads (86%) | catalogued as COSV59814463; called by muse, mutect2, varscan2
- NDST3 | c.2067G>A p.K689= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs566900595, COSV56626480; called by muse, mutect2, varscan2
- NR2F1 | c.810G>A p.P270= | Silent (SNP) | VAF 51/85 reads (60%) | catalogued as rs1561524973, COSV59069626; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT22 | c.237C>A p.L79= | Silent (SNP) | VAF 46/140 reads (33%) | catalogued as COSV54175172; called by muse, mutect2, varscan2
- OGG1 | c.957C>T p.F319= | Silent (SNP) | VAF 14/362 reads (4%) | catalogued as COSV56539931; called by muse, mutect2
- OPTN | c.744G>A p.E248= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV53812468; called by muse, mutect2, varscan2
- OR14C36 | c.756A>T p.S252= | Silent (SNP) | VAF 73/147 reads (50%) | catalogued as COSV58602385; called by muse, mutect2, varscan2
- OR2D3 | c.603G>A p.L201= | Silent (SNP) | VAF 32/38 reads (84%) | catalogued as COSV53494400; called by muse, mutect2, varscan2
- OR2M7 | c.831C>T p.F277= | Silent (SNP) | VAF 50/109 reads (46%) | catalogued as COSV58740242; called by muse, mutect2, varscan2
- ORAI2 | c.402C>T p.I134= | Silent (SNP) | VAF 99/195 reads (51%) | catalogued as COSV62690233; called by muse, mutect2, varscan2
- ORAI3 | c.222C>T p.F74= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs1379532464, COSV57944825; called by muse, mutect2, varscan2
- PCDH9 | c.1650T>A p.P550= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as COSV60578776; called by muse, mutect2, varscan2
- PCDHB9 | c.1899C>T p.R633= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV53383217; called by muse, mutect2, varscan2
- PDCD11 | c.3954C>T p.I1318= | Silent (SNP) | VAF 49/105 reads (47%) | catalogued as COSV63934902; called by muse, mutect2, varscan2
- PIGT | c.603C>G p.L201= | Silent (SNP) | VAF 64/471 reads (14%) | catalogued as COSV54127933; called by muse, mutect2, varscan2
- POLR2A | c.1062G>A p.L354= | Silent (SNP) | VAF 38/45 reads (84%) | catalogued as COSV59494944; called by muse, mutect2, varscan2
- POLR3A | c.1035G>A p.L345= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100965653, COSV64930075; called by muse, mutect2, varscan2
- PRLHR | c.456C>A p.L152= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53304782; called by muse, mutect2, varscan2
- PSMC5 | c.762C>T p.I254= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs765705310, COSV56741330; called by muse, mutect2, varscan2
- RAB2B | c.21C>T p.F7= | Silent (SNP) | VAF 90/103 reads (87%) | catalogued as rs545733102, COSV52970641; called by muse, mutect2, varscan2
- RASGRF1 | c.2289C>T p.I763= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- RNF168 | c.1131G>A p.S377= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs766155334, COSV58839111; ClinVar: likely benign; called by muse, mutect2, varscan2
- RTL10 | c.351C>T p.F117= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as COSV60736193; called by muse, mutect2, varscan2
- SACS | c.5337G>C p.S1779= | Silent (SNP) | VAF 124/231 reads (54%) | catalogued as COSV66543870, COSV66545277; called by muse, mutect2, varscan2
- SEMA4C | c.172C>T p.L58= | Silent (SNP) | VAF 6/111 reads (5%) | catalogued as COSV59690025, COSV59691891; called by muse, mutect2
- SHROOM3 | c.5772C>T p.F1924= | Silent (SNP) | VAF 75/125 reads (60%) | catalogued as rs772343315, COSV56036933, COSV99935104; called by muse, mutect2, varscan2
- SLC4A10 | c.3114G>A p.L1038= (on ENST00000446997 / NM_001354461.2; = p.L1008= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs752841128, COSV55793821; called by muse, mutect2, varscan2
- SMPDL3A | c.663G>A p.L221= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as COSV63755744; called by muse, mutect2, varscan2
- SOD2 | c.426C>T p.V142= | Silent (SNP) | VAF 92/153 reads (60%) | catalogued as COSV61623259, COSV61623284; called by muse, mutect2, varscan2
- SP110 | c.720G>A p.E240= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV51268330; called by muse, mutect2, varscan2
- SRR | c.228G>A p.P76= | Silent (SNP) | VAF 73/82 reads (89%) | catalogued as rs1422705464, COSV56786795; called by muse, mutect2, varscan2
- SRSF5 | c.381C>T p.F127= | Silent (SNP) | VAF 34/42 reads (81%) | catalogued as rs768069967, COSV53683198, COSV53683681; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.276G>A p.Q92= | Silent (SNP) | VAF 62/106 reads (58%) | catalogued as COSV60343823; called by muse, mutect2, varscan2
- STAT3 | c.1449G>A p.L483= | Silent (SNP) | VAF 7/170 reads (4%) | catalogued as COSV52888365; called by muse, mutect2
- TAS2R8 | c.651C>G p.L217= | Silent (SNP) | VAF 49/76 reads (64%) | catalogued as rs561804195, COSV53690243; called by muse, mutect2, varscan2
- TBC1D4 | c.3058C>T p.L1020= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV66490983; called by muse, mutect2, varscan2
- TBCB | c.33G>A p.V11= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as COSV52900595; called by muse, mutect2, varscan2
- TBCE | c.192G>A p.P64= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as rs544392141, COSV64007135; called by muse, mutect2, varscan2
- TEKT1 | c.276C>T p.L92= | Silent (SNP) | VAF 42/51 reads (82%) | catalogued as COSV58624401; called by muse, mutect2, varscan2
- TEX37 | c.180C>T p.P60= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV57556523; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2145C>G p.L715= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV51514998; called by muse, mutect2, varscan2
- TLN2 | c.6624G>C p.L2208= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV60893928; called by muse, mutect2, varscan2
- TMEM175 | c.897C>T p.L299= | Silent (SNP) | VAF 66/165 reads (40%) | catalogued as rs1457908628, COSV53280495; called by muse, mutect2, varscan2
- TMEM245 | c.861C>T p.I287= | Silent (SNP) | VAF 45/50 reads (90%) | catalogued as COSV65824053; called by muse, mutect2, varscan2
- TRIM11 | c.69C>T p.F23= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs902011082, COSV52859425; called by muse, mutect2, varscan2
- TRIM67 | c.108G>A p.V36= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV64159872; called by muse, mutect2, varscan2
- TRPA1 | c.657G>A p.R219= | Silent (SNP) | VAF 48/85 reads (56%) | catalogued as rs770734676, COSV51570611; called by muse, mutect2, varscan2
- TSC2 | c.33G>A p.L11= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs1190907341, COSV54593964; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTC26 | c.780C>T p.I260= | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as COSV58273678; called by muse, mutect2, varscan2
- TTC7A | c.2367G>A p.L789= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as COSV55414250; called by muse, mutect2, varscan2
- TTF2 | c.1236C>A p.A412= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV65633371; called by muse, mutect2, varscan2
- UGT2B28 | c.9G>A p.L3= | Silent (SNP) | VAF 138/399 reads (35%) | catalogued as rs1253225681, COSV59433764; called by muse, mutect2, varscan2
- USP34 | c.9810G>A p.Q3270= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV63725650; called by muse, mutect2, varscan2
- VPS9D1 | c.1809G>C p.L603= | Silent (SNP) | VAF 37/69 reads (54%) | catalogued as COSV66995084; called by muse, mutect2, varscan2
- ZBTB14 | c.1302G>A p.A434= | Silent (SNP) | VAF 68/115 reads (59%) | catalogued as rs776442999, COSV63697177; called by muse, mutect2, varscan2
- ZBTB21 | c.351C>T p.I117= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as rs776567253, COSV60405327; called by muse, mutect2, varscan2
- ZFHX3 | c.1071C>G p.L357= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV51717959, COSV51730352; called by muse, mutect2, varscan2
- ZFHX4 | c.1911G>A p.S637= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs771222216, COSV50640864; called by muse, mutect2, varscan2
- ZFHX4 | c.2337C>A p.A779= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV51486495, COSV51500419; called by muse, mutect2, varscan2
- ZNF589 | c.960C>T p.I320= | Silent (SNP) | VAF 72/139 reads (52%) | catalogued as COSV61220797, COSV61220916; called by muse, mutect2, varscan2
- ATP6V1G3 | c.82+3874G>C | Intron (SNP) | VAF 73/315 reads (23%) | catalogued as COSV55280353; called by muse, mutect2, varscan2
- CDC37P1 | n.199G>A | RNA (SNP) | VAF 31/32 reads (97%) | called by mutect2, varscan2
- DCHS2 | n.5528G>A | RNA (SNP) | VAF 12/58 reads (21%) | catalogued as COSV61777641; called by muse, mutect2, varscan2
- DDX41 | c.*291C>G | 3'UTR (SNP) | VAF 57/106 reads (54%) | catalogued as COSV57253932; called by muse, mutect2, varscan2
- DUSP13 | c.*888G>C | 3'UTR (SNP) | VAF 21/56 reads (38%) | catalogued as COSV57815912; called by muse, mutect2, varscan2
- FAM153CP | chr5:178056045 G>A | 3'Flank (SNP) | VAF 46/76 reads (61%) | called by muse, mutect2, varscan2
- IFT46 | c.46-697G>C | Intron (SNP) | VAF 81/98 reads (83%) | catalogued as COSV50593925, COSV50594986; called by muse, mutect2, varscan2
- OBSCN | c.11659+4251G>A | Intron (SNP) | VAF 6/98 reads (6%) | catalogued as COSV52777550; called by muse, mutect2
- SNORD50B | chr6:85677298 C>G | 3'Flank (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- VNN3 | c.*296G>T | 3'UTR (SNP) | VAF 13/27 reads (48%) | catalogued as COSV51592133; called by muse, mutect2, varscan2
- WBP1LP2 | n.313G>T | RNA (SNP) | VAF 55/62 reads (89%) | called by muse, mutect2, varscan2
